Gene-level copy-number profile of tumor specimen ALCH-B3CG-TTP1-A from ALCHEMIST case ALCH-B3CG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 58.3 years (21,291 days).
Specimen ALCH-B3CG-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 996b9930-fd86-4fd8-a430-6d6815e23dc8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3CG-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/b73064a9-8fae-4530-ba0e-7fda776ee89f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 10,299; copy number 2: 43,575; copy number 3: 4,823; copy number 4: 144; copy number 5: 5; copy number 6: 7; copy number 7: 4; copy number 9: 1; copy number 10: 1; copy number 12: 2; copy number 13: 2; copy number 25: 2; copy number 26: 1.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:21,298,233–21,951,323, 38 genes: AC068446.2, RNU6-1235P, AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3.
- chr16:1,111,627–1,113,399, 1 gene: AL031598.1.
- chr19:54,923,509–55,001,142, 4 genes (within-gene range 0–2): NLRP7, AC011476.8, NLRP2, AC011476.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 25 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:1,570,073–1,615,325, 2 genes, copy number 5 (within-gene range 3–5): PSMG3-AS1, TFAMP1.
- chr8:144,049,079–144,063,965, 3 genes, copy number 5–13: SMPD5, OPLAH, MIR6846.
- chr14:105,621,116–105,669,843, 3 genes, copy number 6–26 (within-gene range 2–26): MIR8071-1, COPDA1, IGHGP.
- chr16:1,078,781–1,105,461, 3 genes, copy number 5–9: SSTR5, C1QTNF8, AL031713.1.
- chr16:1,221,651–1,225,257, 2 genes, copy number 7 (within-gene range 3–7): TPSG1, AC120498.10.
- chr16:1,240,379–1,242,554, 1 gene, copy number 12: TPSAB1.
- chr16:1,260,952–1,276,522, 2 genes, copy number 7–10: PRSS29P, AC120498.7.
- chr19:1,259,384–1,279,244, 3 genes, copy number 6: CIRBP, CIRBP-AS1, FAM174C.
- chr19:55,349,306–55,363,260, 3 genes, copy number 6: COX6B2, AC020922.1, FAM71E2.
- chr20:54,475,593–54,651,169, 1 gene, copy number 7: DOK5.
- chr21:43,461,960–43,479,534, 2 genes, copy number 25: LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 7,443. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
